Surgical pathology report (de-identified scan), TCGA case TCGA-BB-A5HZ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-A5HZ-01A (Primary Tumor).

[page 1 of 2]
SURG PATH REPORT

Carcinoma, squamous cell NOS
8676/3
Site: Oral Cavity C06.9
gn 1/28/13

FINAL DIAGNOSIS ----- Primary Pathologist:

Other Pathologist:

1. UPPER LIP SKIN MARGIN #1 (EXCISION): NEGATIVE FOR TUMOR.
2. LOWER LIP SKIN MARGIN #2 (EXCISION): NEGATIVE FOR TUMOR.
3. MARGIN #3 (EXCISION): NEGATIVE FOR TUMOR.
4. MARGIN #4 (EXCISION): NEGATIVE FOR TUMOR.
5. MARGIN #5 (EXCISION): NEGATIVE FOR TUMOR.
6. MARGIN #6 (EXCISION): NEGATIVE FOR TUMOR.
7. MARGIN #7 (EXCISION): NEGATIVE FOR TUMOR.
8. RIGHT CHEEK MARGIN #8 (EXCISION): NEGATIVE FOR TUMOR. FOCAL FOREIGN BODY GIANT CELL REACTION.
9. UPPER LIP MUCOSA MARGIN (EXCISION): NEGATIVE FOR TUMOR.
10. LOWER LIP MUCOSA MARGIN (EXCISION): NEGATIVE FOR TUMOR.
11. MAXILLARY BUCCAL GINGIVAL SULCUS (EXCISION): NEGATIVE FOR TUMOR.
12. RETROMOLAR TRIGONE MARGIN (EXCISION): NEGATIVE FOR TUMOR.
13. FLOOR OF MOUTH MARGIN (EXCISION): NEGATIVE FOR TUMOR.
14. MANDIBLE AND CHEEK (COMPOSITE RESECTION):
- SPECIMEN TYPE:
Resection (specify type): mandible and cheek.

TUMOR SITE:
Oral Cavity.

TUMOR SIZE:
Greatest dimension: 7.5cm.

HISTOLOGIC TYPE:
Carcinomas of upper aerodigestive tract: squamous cell carcinoma, conventional.

HISTOLOGIC GRADE:
G2: Moderately differentiated.

EXTENT OF INVASION (7th Edition AJCC):
PRIMARY TUMOR (pT):
pT4a: Oral cavity: tumor invades skin of face.

REGIONAL LYMPH NODES (pN):
pN1: Metastasis in a single ipsilateral lymph node, 3cm or less in great dimension. See note.
Specify: Number examined: 39.
Number involved: 1
Extracapsular Extension of Nodal Tumor: Present.

MARGINS:
Margins uninvolved by tumor (see parts 1-13).

*** Unofficial lab results - do not file in patient chart. ***
*** Contact medical records for official chart copy. ***
UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

[page 2 of 2]
VENOUS/LYMPHATIC (LARGE/SMALL VESSEL) INVASION:
Indeterminate.

PERINEURAL INVASION:
Indeterminate.

Note: The involved node is present in the main resection specimen.
The tumor focus is 0.2 cm in greatest dimension.

15. LYMPH NODES, RIGHT NECK (DISSECTION): THIRTY SEVEN (37) LYMPH
NODES AND BENIGN SALIVARY TISSUE, NEGATIVE FOR TUMOR.

*** Unofficial lab results - do not file in patient chart. ***

*** Contact medical records for official chart copy. ***

UNLESS OTHERWISE NOTED ON THE DETAIL PAGE, ALL LAB RESULTS PERFORMED AT:

Case #	112413	Yes	No
Diagnostic Discrepancy			✓
Primary/Former Site Discrepancy			✓
Pathologic Discrepancy			✓

Source: NCI Genomic Data Commons file 1b7bfa41-b8c5-41cc-9187-97982f149ae4 (TCGA-BB-A5HZ.DF88E41E-7CBD-468E-9D42-A2D7AEA8183B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).